Somatic mutation profile of cancer-model specimen HCM-CSHL-0378-C18-85A (3D Organoid; aliquot HCM-CSHL-0378-C18-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-CSHL-0378-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 49.6 years (18,104 days).
Specimen HCM-CSHL-0378-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3df806c5-6780-41ff-a8b4-726054fbed6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0378-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0378-C18-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d11d9ae0-a36f-413d-83f5-5fadcd32520d

The open-access MAF lists 2,849 somatic variants for this specimen: 2,093 protein-altering or splice-affecting, 647 silent, 109 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,492, Silent 647, Frame Shift Del 304, Frame Shift Ins 191, Intron 68, Nonsense Mutation 60, Splice Site 18, Splice Region 18, 3'UTR 17, 5'Flank 10, 3'Flank 7, In Frame Del 7.

Variants (750 of 2,849; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219dup p.R74Qfs*11 | Frame Shift Ins (INS) | VAF 151/322 reads (47%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, varscan2
- AGL | c.4221del p.K1407Nfs*8 | Frame Shift Del (DEL) | VAF 134/244 reads (55%) | catalogued as rs786204655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 68/146 reads (47%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- ALMS1 | c.11083del p.S3695Afs*27 | Frame Shift Del (DEL) | VAF 104/214 reads (49%) | catalogued as rs1412574975, CM074695; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- BTK | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 149/149 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs128621202, CM940197, COSV58117884, COSV58122224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDK13 | c.2995C>T p.R999* | Nonsense Mutation (SNP) | VAF 17/220 reads (8%) | catalogued as rs1175530571; ClinVar: likely pathogenic; called by muse, mutect2
- HNF1A | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 152/321 reads (47%) | catalogued as rs1057520291, CM093342, CM971451, COSV57458707; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 40/164 reads (24%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- MECP2 | c.1086del p.K363Rfs*46 | Frame Shift Del (DEL) | VAF 242/334 reads (72%) | catalogued as rs587783092; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- METTL14 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 97/204 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, mutect2, varscan2
- MSH2 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 127/291 reads (44%) | catalogued as rs63750508, CM960990, COSV51878201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 119/212 reads (56%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- NPHS1 | c.2225T>C p.I742T | Missense Mutation (SNP) | VAF 128/256 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs386833908, CM119056; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NT5C3A | c.671A>G p.N224S (on ENST00000610140 / NM_001374335.1; = p.N190S on NM_016489.13) | Missense Mutation (SNP) | VAF 132/317 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104894028, CM032023; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 203/555 reads (37%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1638G>T p.Q546H | Missense Mutation (SNP) | VAF 92/212 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1057519940, COSV55883555, COSV55928679, COSV55957396; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKD2 | c.2159dup p.N720Kfs*5 | Frame Shift Ins (INS) | VAF 86/178 reads (48%) | catalogued as rs757757289; ClinVar: pathogenic; called by mutect2, varscan2
- PRKD1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1439477100, COSV59566777; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 109/266 reads (41%) | hotspot (GDC flag); catalogued as rs1554898097, COSV64289174; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 70/233 reads (30%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RAD51 | c.855dup p.P286Tfs*37 | Frame Shift Ins (INS) | VAF 153/374 reads (41%) | catalogued as rs34091239; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 126/270 reads (47%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- RYR1 | c.3801del p.C1268Afs*4 | Frame Shift Del (DEL) | VAF 226/594 reads (38%) | catalogued as rs587784374; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SCN5A | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 186/386 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199473058, CM100628, COSV60067722; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/183 reads (15%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA1 | c.5317G>A p.V1773M | Missense Mutation (SNP) | VAF 214/386 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs370103164; called by muse, mutect2, varscan2
- ABCA13 | c.8821C>T p.L2941F | Missense Mutation (SNP) | VAF 143/287 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs1371097227; called by muse, mutect2, varscan2
- ABCA2 | c.6136C>T p.R2046W (on ENST00000614293; = p.R2016W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs747377496; called by muse, mutect2, varscan2
- ABCA7 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 228/489 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752117203; called by muse, mutect2, varscan2
- ABCA9 | c.4198G>A p.A1400T | Missense Mutation (SNP) | VAF 131/278 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as rs1386994010, COSV60623882; called by muse, mutect2, varscan2
- ABCA9 | c.3440T>C p.V1147A | Missense Mutation (SNP) | VAF 89/163 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1446310482; called by muse, mutect2, varscan2
- ABCB11 | c.3305C>T p.S1102L | Missense Mutation (SNP) | VAF 249/486 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs762737233; called by muse, mutect2, varscan2
- ABCC1 | c.2643C>T p.N881= | Splice Region (SNP) | VAF 176/343 reads (51%) | catalogued as rs369748051; called by muse, mutect2, varscan2
- ABCG5 | c.514A>G p.M172V | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs1356083573; called by muse, mutect2, varscan2
- ABI3BP | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 100/210 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as rs374566927; called by muse, mutect2, varscan2
- ABRAXAS1 | c.87+1G>A p.X29_splice | Splice Site (SNP) | VAF 160/385 reads (42%) | catalogued as rs1283259911; called by muse, mutect2, varscan2
- AC004922.1 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 263/503 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149744141; called by muse, mutect2, varscan2
- AC011462.1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 278/549 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.319); catalogued as rs536540966, COSV54195750; called by muse, varscan2
- ACACB | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 228/437 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268082822; called by muse, mutect2, varscan2
- ACACB | c.3416G>A p.R1139H | Missense Mutation (SNP) | VAF 141/293 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs758575862; called by muse, mutect2, varscan2
- ACO2 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 224/440 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.078); catalogued as rs142767544; ClinVar: uncertain significance; called by muse, varscan2
- ACOX2 | c.1413_1414dup p.P472Lfs*38 | Frame Shift Ins (INS) | VAF 66/396 reads (17%) | catalogued as rs759803386; called by mutect2, varscan2
- ACSM5 | c.624-1G>T p.X208_splice | Splice Site (SNP) | VAF 122/224 reads (54%) | catalogued as COSV100088188, COSV100089757; called by muse, mutect2, varscan2
- ACTRT2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 124/594 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763403198; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 224/232 reads (97%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS20 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 132/288 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336951473; called by muse, mutect2, varscan2
- ADAMTS8 | c.2434G>A p.V812M | Missense Mutation (SNP) | VAF 232/500 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs573455313; called by muse, mutect2
- ADAMTSL5 | c.979dup p.V327Gfs*29 | Frame Shift Ins (INS) | VAF 273/856 reads (32%) | catalogued as rs939737122; called by pindel, varscan2
- ADCY4 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 92/213 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150810366; called by muse, varscan2
- ADGRB3 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs754848273, COSV65395147, COSV65421513; called by muse, mutect2, varscan2
- ADGRL1 | c.1937A>G p.H646R (on ENST00000340736 / NM_001008701.3; = p.H641R on NM_014921.5) | Missense Mutation (SNP) | VAF 340/649 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.208); catalogued as rs149369702; called by muse, mutect2, varscan2
- ADGRL1 | c.1716_1718del p.S573del (on ENST00000340736 / NM_001008701.3; = p.S568del on NM_014921.5) | In Frame Del (DEL) | VAF 233/526 reads (44%) | catalogued as rs752164846; called by pindel, varscan2
- ADH6 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 144/316 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778701583, COSV52956709; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 75/190 reads (39%) | catalogued as rs779815391; called by mutect2, pindel, varscan2
- AGAP6 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 137/249 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs781796496; called by muse, mutect2, varscan2
- AGBL2 | c.2482del p.L828Wfs*8 | Frame Shift Del (DEL) | VAF 112/240 reads (47%) | catalogued as rs1310675921; called by mutect2, varscan2
- AGO3 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs765473330; called by muse, mutect2, varscan2
- AGRN | c.2894G>A p.S965N | Missense Mutation (SNP) | VAF 76/456 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.855); catalogued as rs779593673; called by muse, varscan2
- AIRE | c.1483C>A p.L495M | Missense Mutation (SNP) | VAF 189/439 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.135); catalogued as COSV52393870; called by muse, mutect2, varscan2
- AKAP11 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 166/391 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV50292403; called by muse, mutect2, varscan2
- AKR7A3 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 159/309 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780744277, COSV64389285; called by muse, mutect2, varscan2
- AKT1S1 | c.13C>T p.R5C (on ENST00000344175 / NM_001098633.4; = p.R25C on NM_032375.5) | Missense Mutation (SNP) | VAF 307/647 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1568668304; called by muse, mutect2, varscan2
- ALDH2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 170/371 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs1201887042; called by muse, mutect2, varscan2
- AMBRA1 | c.3278G>A p.R1093Q (on ENST00000458649 / NM_001367468.1; = p.R1003Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 271/534 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs768258869, COSV54056628; called by muse, mutect2, varscan2
- ANGEL1 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 204/402 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs370876261; called by muse, mutect2, varscan2
- ANHX | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs767542667, COSV101376534; called by muse, mutect2, varscan2
- ANKRD16 | c.920dup p.N307Kfs*29 | Frame Shift Ins (INS) | VAF 15/119 reads (13%) | catalogued as rs757972825; called by mutect2, varscan2
- ANKRD17 | c.4063A>T p.T1355S | Missense Mutation (SNP) | VAF 140/296 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV58223444; called by muse, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD30A | c.2031A>C p.Q677H (on ENST00000611781; = p.Q621H on NM_052997.2) | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV64613100; called by muse, mutect2, varscan2
- ANKRD31 | c.3886C>T p.R1296W | Missense Mutation (SNP) | VAF 93/177 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs766084000, COSV57163884; called by muse, mutect2, varscan2
- ANKRD33 | c.223C>T p.R75W (on ENST00000340970 / NM_001304459.2; = p.R210W on NM_182608.4) | Missense Mutation (SNP) | VAF 200/422 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs144402270; called by muse, mutect2, varscan2
- ANKS3 | c.1854del p.E619Sfs*19 | Frame Shift Del (DEL) | VAF 180/492 reads (37%) | catalogued as rs1387325245, COSV58512009; called by mutect2, pindel, varscan2
- AOC2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 258/577 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1555552227, COSV53199505; called by muse, mutect2, varscan2
- AP002495.1 | c.482G>A p.R161H (on ENST00000528511; = p.R92H on NM_001375848.1) | Missense Mutation (SNP) | VAF 172/367 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as rs1195569691; called by muse, mutect2, varscan2
- AP2A1 | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 170/379 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1568590762; called by muse, mutect2, varscan2
- APOB | c.6310A>G p.I2104V | Missense Mutation (SNP) | VAF 151/330 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs1270061625; called by muse, mutect2, varscan2
- APOB | c.5752G>A p.A1918T | Missense Mutation (SNP) | VAF 181/327 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs761213870, COSV51950350, COSV51950670, COSV51952304; called by muse, mutect2, varscan2
- APOBEC3C | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 194/439 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs141108460; called by muse, mutect2, varscan2
- ARFGAP3 | c.669del p.G224Afs*32 | Frame Shift Del (DEL) | VAF 33/79 reads (42%) | catalogued as rs1436718702, COSV54312627; called by mutect2, pindel, varscan2
- ARFGEF3 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 173/430 reads (40%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.986); catalogued as rs145746277; called by muse, mutect2, varscan2
- ARFGEF3 | c.3265C>T p.R1089W | Missense Mutation (SNP) | VAF 340/660 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1030633854; called by muse, mutect2, varscan2
- ARFRP1 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 155/337 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.144); catalogued as rs963773082; called by muse, mutect2, varscan2
- ARG2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 104/225 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs1177935795; called by muse, mutect2, varscan2
- ARHGAP1 | c.709dup p.L237Pfs*74 | Frame Shift Ins (INS) | VAF 158/336 reads (47%) | catalogued as rs778464663; called by mutect2, varscan2
- ARHGAP1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 147/282 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs760960194, COSV100358100; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP15 | c.723T>A p.S241R | Missense Mutation (SNP) | VAF 105/229 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs1399037546; called by muse, mutect2, varscan2
- ARHGAP17 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 165/340 reads (49%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as rs769354198, COSV51507570; called by muse, mutect2
- ARHGAP18 | c.1877dup p.L626Ffs*3 | Frame Shift Ins (INS) | VAF 86/204 reads (42%) | catalogued as rs866380047; called by mutect2, varscan2
- ARHGAP24 | c.1714C>T p.R572C (on ENST00000395184 / NM_001025616.3; = p.R479C on NM_031305.3) | Missense Mutation (SNP) | VAF 212/484 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs1176128263; called by muse, mutect2, varscan2
- ARHGAP45 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 368/798 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1273604156; called by muse, mutect2
- ARHGEF12 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 162/337 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1365120600; called by muse, mutect2, varscan2
- ARHGEF16 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 275/570 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs372889057; called by muse, mutect2, varscan2
- ARHGEF17 | c.4433G>A p.S1478N | Missense Mutation (SNP) | VAF 158/291 reads (54%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs143335635; called by muse, mutect2, varscan2
- ARHGEF26 | c.244dup p.L82Pfs*70 | Frame Shift Ins (INS) | VAF 224/554 reads (40%) | catalogued as rs1316487152; called by mutect2, pindel, varscan2
- ARHGEF33 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 171/362 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1371817681; called by muse, mutect2, varscan2
- ARID2 | c.1684C>A p.L562I | Missense Mutation (SNP) | VAF 106/208 reads (51%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV100536699; called by muse, mutect2, varscan2
- ARL5A | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs756366503; called by muse, mutect2, varscan2
- ARRDC2 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 412/776 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs200200467; called by muse, mutect2, varscan2
- ART5 | c.157dup p.L53Pfs*116 | Frame Shift Ins (INS) | VAF 187/451 reads (41%) | catalogued as rs764827799; called by mutect2, pindel, varscan2
- ASB4 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 252/508 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1171585090; called by muse, mutect2, varscan2
- ASCC3 | c.1058dup p.A354Gfs*15 | Frame Shift Ins (INS) | VAF 102/244 reads (42%) | catalogued as rs1361297712; called by mutect2, varscan2
- ASPM | c.4898G>A p.R1633H | Missense Mutation (SNP) | VAF 126/276 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs181624297, COSV54130632, COSV54131811; called by muse, mutect2, varscan2
- ASXL3 | c.3584C>T p.A1195V | Missense Mutation (SNP) | VAF 170/313 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as rs752566392; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 175/448 reads (39%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATG9A | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 208/451 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs61747685, COSV100772500; called by muse, varscan2
- ATM | c.5959T>C p.S1987P | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1421604744; called by muse, mutect2, varscan2
- ATP10D | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 211/403 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs773685085, COSV56704660; called by muse, mutect2, varscan2
- ATP10D | c.1058dup p.N354Qfs*6 | Frame Shift Ins (INS) | VAF 168/415 reads (40%) | catalogued as rs911237323; called by mutect2, pindel, varscan2
- ATP10D | c.3187A>G p.M1063V | Missense Mutation (SNP) | VAF 135/252 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1208769164; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 47/97 reads (48%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP1A3 | c.1820G>A p.G607D (on ENST00000545399 / NM_001256214.2; = p.G594D on NM_152296.5) | Missense Mutation (SNP) | VAF 116/486 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV100132638; called by muse, mutect2, varscan2
- ATP2A1 | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 226/463 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs764667200, COSV100706776; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs575884895; called by muse, mutect2, varscan2
- ATP8B2 | c.1030C>T p.P344S (on ENST00000672630; = p.P311S on NM_001005855.2) | Missense Mutation (SNP) | VAF 215/403 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); catalogued as COSV59247187; called by muse, mutect2, varscan2
- ATRAID | c.666G>T p.E222D (on ENST00000611786; = p.E109D on NM_016085.5) | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV104391635, COSV53025675; called by muse, mutect2, varscan2
- ATXN1L | c.1377del p.I460Lfs*11 | Frame Shift Del (DEL) | VAF 238/567 reads (42%) | catalogued as COSV70234780; called by mutect2, pindel, varscan2
- ATXN2 | c.962G>A p.R321H (on ENST00000550104; = p.R161H on NM_002973.4) | Missense Mutation (SNP) | VAF 143/348 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1051375712, COSV101112699; called by muse, mutect2, varscan2
- B4GALNT4 | c.190dup p.V64Gfs*11 | Frame Shift Ins (INS) | VAF 135/368 reads (37%) | catalogued as rs1331097095; called by mutect2, pindel, varscan2
- B4GALT5 | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 133/278 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.104); catalogued as COSV65494942, COSV65495436; called by muse, mutect2, varscan2
- B9D2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 130/632 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.576); catalogued as COSV54684092; called by muse, mutect2, varscan2
- BAHCC1 | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 74/662 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as rs375834153; called by muse, varscan2
- BAP1 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 244/483 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs748853790, COSV56230849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAN | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 179/391 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs762033515, COSV61256821; called by muse, mutect2, varscan2
- BCAT2 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 270/622 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.492); catalogued as rs202101618; called by muse, mutect2, varscan2
- BCL6B | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 247/442 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1431084194, COSV53427242; called by muse, mutect2, varscan2
- BCL9 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 40/596 reads (7%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.588); catalogued as rs782801902; called by muse, mutect2
- BCL9L | c.1346del p.P449Lfs*14 | Frame Shift Del (DEL) | VAF 134/286 reads (47%) | catalogued as rs754310793, COSV52681762; called by mutect2, pindel
- BCORL1 | c.4091G>A p.R1364H | Missense Mutation (SNP) | VAF 177/180 reads (98%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs753405048, COSV54394085; called by muse, mutect2, varscan2
- BICDL2 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 89/527 reads (17%) | catalogued as rs752116624; called by muse, mutect2, varscan2
- BICRA | c.3467G>A p.R1156Q | Missense Mutation (SNP) | VAF 197/438 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1194396098, COSV67604241; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 162/447 reads (36%) | catalogued as rs772920507, COSV65808737; called by pindel, varscan2
- BOP1 | c.106dup p.L36Pfs*34 | Frame Shift Ins (INS) | VAF 148/294 reads (50%) | catalogued as rs782133829; called by mutect2, varscan2
- BRCA1 | c.3809G>A p.C1270Y | Missense Mutation (SNP) | VAF 118/245 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.403); catalogued as rs1207787135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD1 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 136/575 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs548074999, COSV53454349; called by muse, mutect2, varscan2
- BRIP1 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747568830, COSV52002146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRSK1 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 303/694 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1375075461, COSV58670131; called by muse, mutect2, varscan2
- BSG | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 91/428 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs774867811; called by muse, mutect2, varscan2
- BTBD7 | c.3003dup p.Q1002Tfs*5 | Frame Shift Ins (INS) | VAF 200/532 reads (38%) | catalogued as rs762347380; called by mutect2, pindel, varscan2
- BTBD8 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 106/257 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774884224, COSV64883698; called by muse, mutect2, varscan2
- BTC | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs782514658, COSV67547635; called by muse, mutect2, varscan2
- BTNL2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 165/348 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.425); catalogued as rs778673342; called by muse, mutect2, varscan2
- BUD31 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 176/376 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs535879217; called by muse, mutect2, varscan2
- C11orf49 | c.217del p.H73Tfs*24 | Frame Shift Del (DEL) | VAF 53/319 reads (17%) | catalogued as rs780813798; called by mutect2, pindel, varscan2
- C16orf70 | c.1230dup p.R411Qfs*4 | Frame Shift Ins (INS) | VAF 230/458 reads (50%) | catalogued as rs539297455; called by mutect2, varscan2
- C1QL1 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 156/364 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs762808816; called by mutect2, varscan2
- C1QL3 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.572); catalogued as COSV100126913; called by muse, mutect2
- C1QTNF2 | c.391C>T p.R131W (on ENST00000393975; = p.R86W on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/289 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs545651547; called by muse, mutect2, varscan2
- C1orf127 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 156/319 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs780994813; called by muse, mutect2, varscan2
- C20orf203 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 237/480 reads (49%) | catalogued as rs1296650325; called by muse, mutect2, varscan2
- C2orf16 | c.3880G>A p.G1294R | Missense Mutation (SNP) | VAF 142/266 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.761); catalogued as rs940812968; called by muse, mutect2, varscan2
- C3orf18 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 227/450 reads (50%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs577414859, COSV51750127; called by muse, mutect2, varscan2
- C6orf47 | c.481del p.E161Nfs*22 | Frame Shift Del (DEL) | VAF 383/969 reads (40%) | catalogued as rs1396655057; called by mutect2, pindel, varscan2
- C6orf52 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 146/296 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.436); catalogued as rs369487510; called by muse, mutect2, varscan2
- CAB39L | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 145/294 reads (49%) | catalogued as rs1254047124, COSV61713428; called by muse, mutect2, varscan2
- CABIN1 | c.1509G>A p.W503* | Nonsense Mutation (SNP) | VAF 170/412 reads (41%) | catalogued as rs1410666472; called by muse, mutect2, varscan2
- CACNA1B | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 174/360 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1402354374, COSV99497876; called by muse, mutect2, varscan2
- CACNA1C | c.5788C>T p.L1930F (on ENST00000399634 / NM_001167625.1; = p.L1859F on NM_000719.7) | Missense Mutation (SNP) | VAF 129/277 reads (47%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV100215659; called by muse, mutect2, varscan2
- CACNG1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 183/412 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs140761602; called by muse, mutect2, varscan2
- CACNG6 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 142/314 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as rs147457475; called by muse, mutect2, varscan2
- CAD | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 227/453 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs778021382; called by muse, mutect2, varscan2
- CAMSAP3 | c.3037C>T p.R1013W | Missense Mutation (SNP) | VAF 344/681 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV104381722; called by muse, mutect2, varscan2
- CASZ1 | c.3328G>A p.V1110M | Missense Mutation (SNP) | VAF 144/725 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs1445358610, COSV59740024; called by muse, mutect2, varscan2
- CBFA2T3 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 252/506 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs746822548, COSV51930229; called by muse, varscan2
- CC2D2A | c.245G>A p.R82Q (on ENST00000424120 / NM_001378615.1; = p.T117= on NM_020785.2) | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs527974001; called by muse, mutect2, varscan2
- CCDC138 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 125/264 reads (47%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs773195278; called by muse, mutect2, varscan2
- CCDC14 | c.439G>T p.D147Y (on ENST00000488653; = p.D99Y on NM_022757.5) | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV59945655; called by muse, mutect2, varscan2
- CCDC146 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768291542; called by muse, mutect2, varscan2
- CCDC154 | c.1825C>T p.R609W | Missense Mutation (SNP) | VAF 333/653 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs765670349, COSV101209704; called by muse, mutect2, varscan2
- CCDC168 | c.15141dup p.L5048Ifs*6 | Frame Shift Ins (INS) | VAF 104/278 reads (37%) | catalogued as rs1248067507; called by mutect2, pindel, varscan2
- CCDC180 | c.4288A>G p.T1430A | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1360068205; called by muse, mutect2, varscan2
- CCDC191 | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 123/254 reads (48%) | catalogued as rs761565825, COSV55670186; called by muse, mutect2, varscan2
- CCDC61 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 182/403 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as rs377161841, COSV54430665; called by muse, mutect2, varscan2
- CCDC65 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs749566430; called by muse, mutect2
- CCDC96 | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 291/632 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1295651118; called by muse, mutect2, varscan2
- CCIN | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 58/386 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs374729826; called by muse, mutect2, varscan2
- CCL26 | c.237dup p.W80Mfs*44 | Frame Shift Ins (INS) | VAF 123/311 reads (40%) | catalogued as rs1266314991; called by mutect2, pindel, varscan2
- CCNO | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 297/650 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1561121754; called by mutect2, varscan2
- CD163L1 | c.4071A>G p.S1357= | Splice Region (SNP) | VAF 38/177 reads (21%) | catalogued as rs1394850917; called by muse, varscan2
- CD180 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 164/377 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs140099362; called by muse, mutect2, varscan2
- CD47 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62526472, COSV62528602; called by muse, mutect2
- CD96 | c.598A>G p.N200D (on ENST00000283285 / NM_198196.3; = p.N184D on NM_005816.5) | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV51923816; called by muse, mutect2, varscan2
- CDC14A | c.1187del p.G396Efs*7 | Frame Shift Del (DEL) | VAF 176/400 reads (44%) | catalogued as COSV100325025; called by mutect2, pindel, varscan2
- CDC42BPB | c.2347C>A p.L783I | Missense Mutation (SNP) | VAF 130/232 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs747896976; called by muse, mutect2, varscan2
- CDH1 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 304/590 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs746464544, COSV55737603; called by muse, varscan2
- CDH18 | c.2087A>G p.K696R | Missense Mutation (SNP) | VAF 135/281 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs372756197; called by muse, mutect2, varscan2
- CDH4 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 221/487 reads (45%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.971); catalogued as rs757336738, COSV64650871; called by muse, mutect2, varscan2
- CDH9 | c.2104A>G p.R702G | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs1297156742, COSV50323819; called by muse, mutect2
- CDKL1 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 113/230 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs149593906; called by muse, mutect2, varscan2
- CDRT15 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 55/410 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs770684495; called by muse, varscan2
- CEACAM6 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 103/283 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as rs782518779, COSV52266363; called by muse, mutect2, varscan2
- CEBPZ | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 157/316 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774537350; called by muse, mutect2, varscan2
- CEP295 | c.7175G>A p.G2392D | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265555252; called by muse, mutect2, varscan2
- CFAP20 | c.279A>G p.V93= | Splice Region (SNP) | VAF 18/278 reads (6%) | catalogued as rs755515452; called by muse, mutect2
- CFAP65 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 239/546 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404439204, COSV100445447; called by muse, varscan2
- CHD1L | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1455863597; called by muse, mutect2, varscan2
- CHD3 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 140/323 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV100390551; called by muse, varscan2
- CHD4 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 148/305 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs755840734; called by muse, mutect2, varscan2
- CHD5 | c.5396C>T p.A1799V | Missense Mutation (SNP) | VAF 178/425 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV52407184; called by muse, mutect2, varscan2
- CHMP2A | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 194/392 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53397313; called by muse, varscan2
- CHPF | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 285/593 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs138114486; called by muse, varscan2
- CHST11 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 162/341 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs755609952; called by muse, mutect2, varscan2
- CHST8 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 308/666 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755337339, COSV52858646; called by muse, mutect2, varscan2
- CIC | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 312/647 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs781702039; called by muse, mutect2, varscan2
- CIDEC | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 199/424 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1418902123; called by muse, mutect2, varscan2
- CILP2 | c.2191G>A p.V731M | Missense Mutation (SNP) | VAF 392/817 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV99365031; called by muse, mutect2, varscan2
- CIP2A | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 119/241 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255756155; called by muse, mutect2, varscan2
- CIT | c.4051C>T p.R1351W | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs138439879, COSV55875701; called by muse, mutect2, varscan2
- CITED1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 331/335 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55744420; called by muse, mutect2, varscan2
- CLEC1B | c.63C>T p.S21= | Splice Region (SNP) | VAF 86/180 reads (48%) | catalogued as rs753747323, COSV100046153; called by muse, mutect2, varscan2
- CLIP2 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 273/554 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1191341904, COSV56274791; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 46/118 reads (39%) | catalogued as rs369752219; called by mutect2, varscan2
- CNBD1 | c.1260A>C p.K420N | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV73073150; called by muse, mutect2, varscan2
- CNBP | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs1434491550; called by muse, mutect2, varscan2
- CNTLN | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.127); catalogued as COSV52067119; called by muse, mutect2, varscan2
- CNTNAP2 | c.726dup p.A243Sfs*31 | Frame Shift Ins (INS) | VAF 62/199 reads (31%) | catalogued as rs1225661805; called by pindel, varscan2
- CNTNAP3 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 332/688 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs886759823; called by muse, mutect2, varscan2
- CNTNAP5 | c.2988dup p.E997Rfs*7 | Frame Shift Ins (INS) | VAF 88/242 reads (36%) | catalogued as rs1486530067; called by mutect2, pindel, varscan2
- CNTRL | c.845del p.K282Rfs*2 | Frame Shift Del (DEL) | VAF 60/134 reads (45%) | catalogued as rs750317819; called by mutect2, pindel, varscan2
- CNTRL | c.1336del p.I446* | Frame Shift Del (DEL) | VAF 28/162 reads (17%) | catalogued as rs747099268; called by mutect2, varscan2
- COG4 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 193/437 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV60424870; called by muse, mutect2, varscan2
- COL15A1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 169/377 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs746005741, COSV66642852, COSV66645456; called by muse, mutect2, varscan2
- COL16A1 | c.4059A>G p.G1353= | Splice Region (SNP) | VAF 144/323 reads (45%) | catalogued as rs775037009; called by muse, mutect2, varscan2
- COL21A1 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV55161750; called by muse, mutect2, varscan2
- COL22A1 | c.4642G>T p.G1548C | Missense Mutation (SNP) | VAF 218/509 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100278423; called by muse, mutect2, varscan2
- COL4A2 | c.4275dup p.G1426Rfs*30 | Frame Shift Ins (INS) | VAF 114/274 reads (42%) | catalogued as rs34603892; called by mutect2, varscan2
- COL5A2 | c.4468G>A p.G1490S | Missense Mutation (SNP) | VAF 150/338 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775322653, COSV66410843; called by muse, varscan2
- COL7A1 | c.2615C>T p.T872M | Missense Mutation (SNP) | VAF 296/553 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs761872531, COSV60402701; called by muse, mutect2, varscan2
- COL7A1 | c.2586G>A p.T862= | Splice Region (SNP) | VAF 169/295 reads (57%) | catalogued as rs537416600, COSV60398785; called by muse, mutect2, varscan2
- COMMD2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 161/327 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs781184439; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 91/202 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as rs754165911; called by muse, mutect2, varscan2
- COPS6 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 132/299 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.228); catalogued as rs558924563, COSV100384752; called by muse, mutect2, varscan2
- COQ8A | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 167/388 reads (43%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV64657123; called by muse, mutect2, varscan2
- CPT1C | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 187/428 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774069280; called by muse, mutect2, varscan2
- CPXM1 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 150/317 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs375270618; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 127/288 reads (44%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CREB3L2 | c.318C>T p.D106= | Splice Region (SNP) | VAF 95/196 reads (48%) | catalogued as rs770778169, COSV57792712; called by muse, mutect2, varscan2
- CRNN | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 226/427 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV55121108; called by muse, mutect2, varscan2
- CROCC2 | c.4067G>A p.R1356H | Missense Mutation (SNP) | VAF 332/710 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1335822254; called by muse, mutect2, varscan2
- CRYGS | c.1del p.M1? | Frame Shift Del (DEL) | VAF 121/331 reads (37%) | catalogued as rs1431370280; called by mutect2, pindel, varscan2
- CSMD2 | c.7498C>T p.R2500C | Missense Mutation (SNP) | VAF 321/687 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760779955, COSV53890854; called by muse, mutect2, varscan2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 48/226 reads (21%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CTC1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 154/311 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs761903168; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA3 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 186/399 reads (47%) | catalogued as rs202196166, COSV65522010, COSV65522795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNND1 | c.2389C>T p.R797* (on ENST00000399050 / NM_001085458.2; = p.R791* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 107/311 reads (34%) | catalogued as COSV62387156; called by muse, mutect2, varscan2
- CTU1 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 290/592 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1239432964; called by muse, mutect2, varscan2
- CUL9 | c.6704G>A p.R2235H | Missense Mutation (SNP) | VAF 222/472 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs975038563, COSV52728269; called by muse, mutect2, varscan2
- CUL9 | c.6940C>T p.R2314W | Missense Mutation (SNP) | VAF 155/350 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1212337730; called by muse, mutect2, varscan2
- CYP1B1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 255/537 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1272655298, CM148175; called by muse, mutect2, varscan2
- CYP2A7 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 183/323 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.261); catalogued as rs138321167; called by muse, mutect2, varscan2
- CYP2F1 | c.826_828del p.K276del | In Frame Del (DEL) | VAF 54/249 reads (22%) | catalogued as rs1372949066; called by mutect2, pindel, varscan2
- CYP4A11 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 171/380 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs758007868; called by muse, mutect2, varscan2
- DAB2 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 206/449 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs758876075; called by muse, mutect2, varscan2
- DAGLB | c.484del p.M162Wfs*114 | Frame Shift Del (DEL) | VAF 167/452 reads (37%) | catalogued as rs755532044; called by mutect2, pindel, varscan2
- DARS2 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 175/348 reads (50%) | catalogued as rs751929342, COSV53408641; called by muse, mutect2, varscan2
- DAXX | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 402/859 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773506568; called by muse, mutect2, varscan2
- DAZAP1 | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 267/588 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.215); catalogued as rs1452285153, COSV51832331; called by muse, mutect2, varscan2
- DCHS1 | c.5065G>A p.V1689I | Missense Mutation (SNP) | VAF 152/355 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1289410605, COSV55042289; called by muse, mutect2, varscan2
- DDB2 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 236/471 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as rs145822896; called by muse, mutect2, varscan2
- DDHD2 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs200605990; called by muse, mutect2, varscan2
- DDOST | c.890G>A p.R297H (on ENST00000415136; = p.R280H on NM_005216.5) | Missense Mutation (SNP) | VAF 187/359 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs754561384; called by muse, varscan2
- DDR2 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 133/265 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM160997, COSV63369117; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 156/346 reads (45%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX18 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 139/296 reads (47%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.713); catalogued as rs199589040; called by muse, mutect2, varscan2
- DDX50 | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 203/453 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.662); catalogued as rs576789694; called by muse, mutect2, varscan2
- DEAF1 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 218/454 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); catalogued as rs760200310, COSV104385314; called by muse, mutect2, varscan2
- DEFA5 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766579196; called by muse, mutect2
- DEFB135 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 146/331 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.937); catalogued as rs778804110; called by muse, mutect2, varscan2
- DELE1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 146/305 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.215); catalogued as rs748202306; called by muse, varscan2
- DENND2A | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 162/336 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs749243995, COSV52059400; called by muse, mutect2, varscan2
- DENND2C | c.329del p.N110Mfs*23 | Frame Shift Del (DEL) | VAF 77/214 reads (36%) | catalogued as rs1462605800; called by mutect2, pindel, varscan2
- DENND4B | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 214/441 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs762271289; called by muse, mutect2, varscan2
- DENND4B | c.304del p.L102Sfs*197 | Frame Shift Del (DEL) | VAF 153/371 reads (41%) | catalogued as rs747842790; called by mutect2, pindel, varscan2
- DES | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 102/230 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1262288015, CM1510931, COSV64661127; ClinVar: uncertain significance; called by muse, varscan2
- DGAT1 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 190/382 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60048989; called by muse, mutect2, varscan2
- DGCR2 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 150/325 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs986455093; called by muse, mutect2, varscan2
- DHX30 | c.3310G>A p.D1104N (on ENST00000445061 / NM_138615.3; = p.D1065N on NM_014966.3) | Missense Mutation (SNP) | VAF 220/423 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs1307373394; called by muse, mutect2, varscan2
- DHX34 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 71/473 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as rs746602462; called by muse, mutect2, varscan2
- DIDO1 | c.3434G>A p.R1145H | Missense Mutation (SNP) | VAF 184/366 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs993292715; called by muse, mutect2, varscan2
- DIO2 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 172/374 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1170347875; called by muse, varscan2
- DLG4 | c.2011C>T p.R671C (on ENST00000399506 / NM_001321075.3; = p.R714C on NM_001365.4) | Missense Mutation (SNP) | VAF 155/371 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV100263399; called by muse, mutect2, varscan2
- DLK1 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 351/791 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761777204, COSV57992732; called by muse, mutect2, varscan2
- DLL4 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 215/477 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs753073687, COSV51069110; called by muse, mutect2, varscan2
- DMBT1 | c.6388C>T p.R2130C (on ENST00000338354 / NM_001377530.1; = p.R1373C on NM_004406.3) | Missense Mutation (SNP) | VAF 168/354 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.825); catalogued as rs189464773, COSV100352690, COSV57557617; called by muse, mutect2, varscan2
- DMD | c.7269G>T p.K2423N | Missense Mutation (SNP) | VAF 189/189 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV100626251; called by muse, mutect2, varscan2
- DNAH1 | c.7109A>G p.D2370G | Missense Mutation (SNP) | VAF 181/431 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs202011102; called by muse, mutect2, varscan2
- DNAH17 | c.8545G>A p.V2849M | Missense Mutation (SNP) | VAF 132/260 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as rs375711976; called by muse, mutect2, varscan2
- DNAH2 | c.2845G>A p.A949T | Missense Mutation (SNP) | VAF 249/503 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as rs757229761; called by muse, mutect2, varscan2
- DNAH2 | c.13123G>A p.A4375T | Missense Mutation (SNP) | VAF 157/345 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs765844181; called by muse, mutect2, varscan2
- DNAH6 | c.911dup p.N304Kfs*6 | Frame Shift Ins (INS) | VAF 58/128 reads (45%) | catalogued as rs763637561; called by mutect2, varscan2
- DOCK8 | c.1954A>G p.I652V | Missense Mutation (SNP) | VAF 187/362 reads (52%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.524); catalogued as rs1381340726; called by muse, mutect2, varscan2
- DOT1L | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 253/529 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67114059; called by muse, mutect2, varscan2
- DPEP2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 259/516 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1192684935; called by muse, mutect2, varscan2
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 128/264 reads (48%) | catalogued as rs748560644; called by mutect2, varscan2
- DPP8 | c.479G>A p.R160H (on ENST00000341861 / NM_001320875.2; = p.R144H on NM_017743.6) | Missense Mutation (SNP) | VAF 138/322 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373358439, COSV55682381; called by muse, mutect2, varscan2
- DPYD | c.544dup p.M182Nfs*3 | Frame Shift Ins (INS) | VAF 145/328 reads (44%) | catalogued as rs754785410; called by mutect2, pindel, varscan2
- DPYS | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 476/980 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV60907261; called by muse, mutect2, varscan2
- DRC7 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 192/385 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376617944; called by muse, mutect2, varscan2
- DRG2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 196/375 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs749970628; called by muse, mutect2, varscan2
- DSCAML1 | c.2443C>T p.R815C (on ENST00000321322; = p.R755C on NM_020693.4) | Missense Mutation (SNP) | VAF 242/509 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs773368695, COSV58390275; called by muse, mutect2, varscan2
- DSG4 | c.2270G>T p.R757M | Missense Mutation (SNP) | VAF 213/433 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100356403; called by muse, mutect2, varscan2
- DSTYK | c.1535T>C p.I512T | Missense Mutation (SNP) | VAF 137/275 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs766114505; called by muse, mutect2, varscan2
- DUSP22 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 146/473 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1230381856, COSV100739692; called by muse, mutect2, varscan2
- DYNC1H1 | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 155/307 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as rs781320162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYRK2 | c.1448G>A p.R483Q (on ENST00000344096 / NM_006482.3; = p.R410Q on NM_003583.4) | Missense Mutation (SNP) | VAF 169/364 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs200239121; called by muse, mutect2, varscan2
- EBF1 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 143/282 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs745519859, COSV58178713; called by muse, mutect2, varscan2
- ECHDC3 | c.417del p.V140Ffs*38 | Frame Shift Del (DEL) | VAF 53/221 reads (24%) | catalogued as rs752908066; called by pindel, varscan2
- ECT2 | c.1159C>A p.L387I (on ENST00000392692 / NM_001349098.2; = p.L356I on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/436 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.119); catalogued as COSV51689476; called by muse, mutect2
- EFCAB13 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs759102054, COSV58950800; called by muse, mutect2, varscan2
- EHBP1L1 | c.3556G>A p.G1186R | Missense Mutation (SNP) | VAF 438/878 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1452760338; called by muse, mutect2, varscan2
- EHD2 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 232/510 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs796785999, COSV54408668; called by muse, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 50/128 reads (39%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EMSY | c.3155C>T p.T1052M | Missense Mutation (SNP) | VAF 199/437 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs201857258, COSV58258795; called by muse, varscan2
- ENO4 | c.1029del p.H345Tfs*21 (on ENST00000622726; = p.H342Tfs*21 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 141/338 reads (42%) | catalogued as rs1156693659; called by mutect2, pindel, varscan2
- ENOX2 | c.832C>T p.R278* (on ENST00000338144 / NM_001382520.1; = p.R249* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 232/233 reads (100%) | catalogued as rs751141125, COSV57647897; called by muse, mutect2, varscan2
- EPB41L5 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1167475492; called by muse, mutect2, varscan2
- EPHA5 | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99895916; called by muse, mutect2, varscan2
- EPPK1 | c.3226G>C p.A1076P | Missense Mutation (SNP) | VAF 235/513 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV101599794; called by muse, mutect2
- EPS15L1 | c.2452G>A p.G818R | Missense Mutation (SNP) | VAF 221/422 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as rs542359984; called by muse, mutect2, varscan2
- ERC1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 133/295 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773843924, COSV61698092; called by muse, mutect2, varscan2
- ERC2 | c.2348T>C p.L783P | Missense Mutation (SNP) | VAF 78/443 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as rs532433820; called by muse, mutect2, varscan2
- ERLEC1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs778793766, COSV51751194; called by muse, mutect2, varscan2
- ERVV-1 | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 195/440 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as rs1308029361; called by muse, mutect2, varscan2
- ETV3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 187/335 reads (56%) | SIFT tolerated (0.95); PolyPhen benign (0.015); catalogued as rs757527481, COSV63865124; called by muse, mutect2, varscan2
- EVPL | c.4117C>T p.Q1373* | Nonsense Mutation (SNP) | VAF 346/736 reads (47%) | catalogued as rs1567907345; called by muse, mutect2, varscan2
- EVPLL | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 214/423 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as rs764103587, COSV67684810; called by muse, mutect2, varscan2
- EXOC3L4 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 394/829 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as rs746720938, COSV66295569; called by muse, mutect2, varscan2
- EXOC7 | c.1556C>T p.T519M (on ENST00000335146 / NM_001145297.4; = p.T437M on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/385 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs1381016469; called by muse, mutect2, varscan2
- EXPH5 | c.4211dup p.N1404Kfs*8 | Frame Shift Ins (INS) | VAF 119/280 reads (43%) | catalogued as rs1251417080; called by mutect2, pindel, varscan2
- F13B | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1553322172; called by muse, mutect2, varscan2
- FABP9 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs1432271886; called by muse, mutect2, varscan2
- FADS3 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs144099007; called by muse, mutect2, varscan2
- FAF1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 97/211 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs772628204; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 120/395 reads (30%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM161A | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 13/411 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56764612; called by muse, mutect2
- FAM170A | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 114/279 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs775441770, COSV58926608; called by muse, mutect2, varscan2
- FAM193B | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 267/545 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61557366; called by muse, mutect2, varscan2
- FAM227A | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 156/308 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1028041375, COSV100874785, COSV63376533; called by muse, mutect2, varscan2
- FAM47C | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 123/292 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as rs1556331986, COSV100792382; called by muse, mutect2, varscan2
- FAM53C | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 342/701 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs528140489, COSV53511499; called by muse, mutect2, varscan2
- FAM89B | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 386/758 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs987040586; called by muse, varscan2
- FAM91A1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 109/265 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs750805412; called by muse, mutect2, varscan2
- FARP1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 164/365 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as rs1337642800, COSV100129967; called by muse, mutect2, varscan2
- FARS2 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 159/343 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223957, COSV51165671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTKD1 | c.2220dup p.P741Tfs*8 | Frame Shift Ins (INS) | VAF 80/194 reads (41%) | catalogued as rs758994923; called by mutect2, varscan2
- FASTKD3 | c.428dup p.D144Gfs*3 | Frame Shift Ins (INS) | VAF 140/352 reads (40%) | catalogued as rs773607911; called by mutect2, varscan2
- FAT2 | c.10804G>A p.V3602I | Missense Mutation (SNP) | VAF 242/472 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs549157480, COSV55823482; called by muse, varscan2
- FAT4 | c.7232C>T p.T2411M | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372786128; called by muse, mutect2, varscan2
- FAT4 | c.7594G>A p.G2532R | Missense Mutation (SNP) | VAF 191/376 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.787); catalogued as rs143180806; called by muse, mutect2, varscan2
- FAT4 | c.14008G>T p.G4670* | Nonsense Mutation (SNP) | VAF 101/418 reads (24%) | catalogued as COSV58679330; called by muse, mutect2, varscan2
- FBXL7 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 257/555 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV61643392; called by muse, mutect2, varscan2
- FBXO43 | c.377del p.K126Rfs*33 | Frame Shift Del (DEL) | VAF 81/334 reads (24%) | catalogued as rs1406026740; called by mutect2, pindel, varscan2
- FCMR | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 187/410 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs768410930, COSV65567108; called by muse, mutect2, varscan2
- FGF22 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 180/818 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1053327160, COSV51260890; called by mutect2, varscan2
- FLG2 | c.5927A>G p.H1976R | Missense Mutation (SNP) | VAF 96/391 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1367203766; called by muse, mutect2, varscan2
- FLII | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 190/368 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs768634078; called by muse, mutect2, varscan2
- FLOT2 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 161/371 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749079749, COSV101204819; called by muse, mutect2, varscan2
- FN3KRP | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 123/251 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs756898501; called by muse, mutect2, varscan2
- FOXJ1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 292/633 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs764249412; called by muse, mutect2, varscan2
- FOXRED1 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 159/355 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as rs750326188; called by muse, mutect2, varscan2
- FREM1 | c.4677del p.T1560Qfs*46 | Frame Shift Del (DEL) | VAF 191/455 reads (42%) | catalogued as rs1358593282, COSV66528287; called by mutect2, pindel, varscan2
- FSIP2 | c.10247dup p.E3417Gfs*12 | Frame Shift Ins (INS) | VAF 113/219 reads (52%) | catalogued as rs1370547117; called by mutect2, varscan2
- FSIP2 | c.17129dup p.G5711Rfs*2 | Frame Shift Ins (INS) | VAF 58/284 reads (20%) | catalogued as rs1473730479; called by mutect2, pindel, varscan2
- FSIP2 | c.19584del p.K6528Nfs*5 | Frame Shift Del (DEL) | VAF 16/163 reads (10%) | catalogued as rs781034813; called by mutect2, pindel, varscan2
- FSTL4 | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 192/397 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756468381; called by muse, mutect2, varscan2
- FUT7 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 227/551 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs748593636; called by muse, mutect2, varscan2
- GAL3ST1 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 367/714 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58892935; called by muse, mutect2, varscan2
- GAL3ST2 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 221/410 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs193179667, COSV99510627; called by muse, varscan2
- GARS1 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765644965; called by muse, mutect2, varscan2
- GBA | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 203/452 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1557905102, CM022012, CM142244; called by muse, mutect2, varscan2
- GEMIN5 | c.3469G>A p.V1157M | Missense Mutation (SNP) | VAF 229/484 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs762026001; called by muse, mutect2, varscan2
- GFUS | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 242/480 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs574552976; called by muse, mutect2, varscan2
- GGN | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 396/828 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.019); catalogued as rs761627725, COSV53057065; called by muse, mutect2, varscan2
- GGT7 | c.1124del p.P375Hfs*38 | Frame Shift Del (DEL) | VAF 81/236 reads (34%) | catalogued as COSV60541721; called by mutect2, pindel, varscan2
- GH2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 273/576 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762966262, COSV60426398, COSV60426542; called by muse, mutect2, varscan2
- GIPC1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 360/731 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779711705, COSV61774876; called by muse, varscan2
- GLI2 | c.3310G>A p.A1104T (on ENST00000361492 / NM_001374353.1; = p.A1121T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 291/610 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs368122191; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 90/197 reads (46%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GOLGA7B | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 239/566 reads (42%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.499); catalogued as rs373874556; called by muse, mutect2, varscan2
- GOLGB1 | c.2838dup p.E947Rfs*7 | Frame Shift Ins (INS) | VAF 148/292 reads (51%) | catalogued as rs774978171; called by mutect2, varscan2
- GPR160 | c.715dup p.I239Nfs*28 | Frame Shift Ins (INS) | VAF 74/164 reads (45%) | catalogued as rs748213865; called by mutect2, varscan2
- GPR37 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 182/412 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs1364183688, COSV58255450; called by muse, mutect2, varscan2
- GPR61 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 371/717 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs758107064, COSV63983417; called by muse, mutect2, varscan2
- GPR78 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 169/338 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs776195249, COSV101223950, COSV66764127; called by muse, mutect2, varscan2
- GPRC5B | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 95/498 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); catalogued as rs200955705, COSV56025220; called by muse, mutect2, varscan2
- GPS1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 132/545 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs749842871; called by muse, mutect2, varscan2
- GRIN2C | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 175/365 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs756143433; called by muse, mutect2, varscan2
- GTF2H4 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 226/454 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as rs774016030; called by muse, varscan2
- GYS1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 256/524 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99620776; called by muse, mutect2, varscan2
- HAPLN1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs779648824, COSV57146725; called by muse, mutect2
- HDAC11 | c.810dup p.L271Afs*13 | Frame Shift Ins (INS) | VAF 37/235 reads (16%) | catalogued as rs759521707; called by mutect2, varscan2
- HDAC2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1283304423; called by muse, mutect2, varscan2
- HDAC4 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 246/475 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs750171912, COSV61871497; called by muse, mutect2, varscan2
- HDAC7 | c.2218G>A p.G740R (on ENST00000427332; = p.G779R on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/289 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99316629; called by muse, mutect2, varscan2
- HDAC7 | c.552del p.S185Afs*138 (on ENST00000427332; = p.S224Afs*138 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 226/575 reads (39%) | catalogued as rs1469325700; called by mutect2, pindel, varscan2
- HDGFL1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 376/812 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.143); catalogued as rs1272409412, COSV57751271; called by muse, mutect2, varscan2
- HEATR1 | c.5707A>G p.M1903V | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1421855611; called by muse, mutect2, varscan2
- HECW1 | c.2192C>T p.T731M | Missense Mutation (SNP) | VAF 220/508 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.985); catalogued as rs1202832720, COSV101223463, COSV67824903; called by muse, varscan2
- HECW2 | c.2763del p.V922* | Frame Shift Del (DEL) | VAF 105/279 reads (38%) | catalogued as COSV99646682; called by mutect2, pindel, varscan2
- HERC1 | c.4936G>A p.V1646I | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs780370483, COSV71249250; called by muse, mutect2, varscan2
- HERC2 | c.12523G>A p.G4175S | Missense Mutation (SNP) | VAF 308/590 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55305110; called by muse, mutect2, varscan2
- HERC6 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 192/444 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954842016, COSV99910719; called by muse, mutect2, varscan2
- HHIPL1 | c.1315T>C p.W439R | Missense Mutation (SNP) | VAF 339/721 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1306218991; called by muse, mutect2, varscan2
- HHIPL1 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 156/843 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as rs1361145641, COSV58091869; called by muse, mutect2, varscan2
- HIVEP3 | c.5903C>T p.P1968L | Missense Mutation (SNP) | VAF 222/422 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs550488511; called by muse, mutect2, varscan2
- HLA-DRA | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 166/357 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV66622558; called by muse, mutect2, varscan2
- HMGCS2 | c.829del p.I277Sfs*22 | Frame Shift Del (DEL) | VAF 123/268 reads (46%) | catalogued as rs1557991740, COSV65568693; called by mutect2, pindel, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 74/146 reads (51%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPA1P48 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 225/462 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1428788030; called by muse, mutect2, varscan2
- HOXA5 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 75/528 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs1246298246; called by muse, mutect2, varscan2
- HOXA7 | c.526A>T p.I176F | Missense Mutation (SNP) | VAF 304/636 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54218344; called by muse, mutect2, varscan2
- HOXB8 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 291/616 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1407054793; called by muse, mutect2, varscan2
- HOXD11 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 150/273 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50910555, COSV50911198; called by muse, mutect2, varscan2
- HSD11B1L | c.709dup p.V237Gfs*64 | Frame Shift Ins (INS) | VAF 371/966 reads (38%) | catalogued as rs1323343683; called by mutect2, pindel, varscan2
- HSPA1L | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 187/389 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as rs544557163, COSV100989465; called by muse, mutect2, varscan2
- HSPA1L | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 250/522 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65149103; called by muse, varscan2
- HSPG2 | c.3325G>A p.V1109M | Missense Mutation (SNP) | VAF 245/525 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs777707172, COSV101020631; called by muse, mutect2, varscan2
- HTR1A | c.161dup p.N54Kfs*137 | Frame Shift Ins (INS) | VAF 218/554 reads (39%) | catalogued as rs1455989620; called by mutect2, pindel, varscan2
- HTT | c.8693C>T p.S2898L | Missense Mutation (SNP) | VAF 275/583 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs201699939, COSV100751053; called by muse, mutect2, varscan2
- ICA1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs570072277, COSV55583956; called by muse, mutect2, varscan2
- IDH2 | c.435dup p.T146Dfs*126 | Frame Shift Ins (INS) | VAF 203/421 reads (48%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, varscan2
- IFIH1 | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 159/315 reads (50%) | catalogued as rs750804689, COSV55125658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFRD1 | c.1183C>A p.L395I | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.776); catalogued as COSV50045579; called by muse, mutect2, varscan2
- IFT172 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 162/342 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs755816980; called by muse, mutect2, varscan2
- IGF2BP2 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 151/294 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as rs773508549; called by muse, mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 127/342 reads (37%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 185/459 reads (40%) | catalogued as rs746629447; called by mutect2, pindel, varscan2
- IGSF3 | c.1756C>T p.P586S (on ENST00000369486 / NM_001007237.3; = p.P606S on NM_001542.4) | Missense Mutation (SNP) | VAF 263/603 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1371768974; called by muse, mutect2, varscan2
- IL12RB1 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 225/452 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1242786208; called by muse, mutect2, varscan2
- IL17RA | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 147/261 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1470802868; called by muse, mutect2, varscan2
- IL17RD | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 164/362 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1410646018; called by muse, mutect2
- IL37 | c.100dup p.L34Pfs*31 | Frame Shift Ins (INS) | VAF 178/388 reads (46%) | catalogued as rs1335390716; called by mutect2, pindel, varscan2
- ILF3 | c.1201dup p.Q401Pfs*39 | Frame Shift Ins (INS) | VAF 59/331 reads (18%) | catalogued as rs776942997; called by mutect2, varscan2
- INF2 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1372251508; called by muse, mutect2, varscan2
- INPP5F | c.2553G>A p.M851I | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs766793915; called by muse, mutect2, varscan2
- INPP5K | c.786dup p.R263Tfs*82 | Frame Shift Ins (INS) | VAF 133/326 reads (41%) | catalogued as rs1567548291; called by mutect2, pindel, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 366/742 reads (49%) | catalogued as rs760925109; called by mutect2, varscan2
- INTS7 | c.2866C>T p.R956C | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs779602041; called by mutect2, varscan2
- IQUB | c.1790_1792del p.K597del | In Frame Del (DEL) | VAF 67/171 reads (39%) | catalogued as rs754146879; called by pindel, varscan2
- IRF3 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 291/594 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1336881907, COSV55863700; called by muse, mutect2, varscan2
- IRF8 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 220/462 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs749756916; called by muse, mutect2, varscan2
- ITCH | c.1997G>A p.R666H (on ENST00000262650 / NM_001257137.3; = p.R625H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs776461109, COSV52931657; called by muse, mutect2, varscan2
- ITGA11 | c.2912A>C p.K971T | Missense Mutation (SNP) | VAF 134/280 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as COSV59881442; called by muse, mutect2
- ITGA5 | c.2679del p.K893Nfs*17 | Frame Shift Del (DEL) | VAF 72/387 reads (19%) | catalogued as COSV53216771; called by mutect2, pindel, varscan2
- ITGA7 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 198/400 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.628); catalogued as rs775800333, COSV57692159; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGB5 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 165/320 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV56148066; called by muse, mutect2, varscan2
- ITPKC | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 231/527 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs780625200; called by muse, mutect2, varscan2
- ITPR2 | c.4465G>A p.G1489S | Missense Mutation (SNP) | VAF 124/250 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs774433217; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 297/647 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs760597072, COSV59826591; called by muse, mutect2, varscan2
- JPH2 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 404/860 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs770850932, COSV100881761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JPH3 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 358/769 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1237610213; called by muse, mutect2, varscan2
- KANSL1 | c.2750C>T p.A917V (on ENST00000574590 / NM_001193465.2; = p.A918V on NM_015443.4) | Missense Mutation (SNP) | VAF 201/450 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs764981398, COSV52248713; called by muse, mutect2, varscan2
- KAT2B | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 126/283 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as rs753562073; called by muse, mutect2, varscan2
- KATNIP | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs147867852; called by muse, mutect2, varscan2
- KAZN | c.1301A>G p.Q434R | Missense Mutation (SNP) | VAF 236/476 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs780740521; called by muse, mutect2, varscan2
- KCNAB1 | c.1083G>A p.A361= (on ENST00000490337 / NM_172160.3; = p.A350= on NM_003471.3) | Splice Region (SNP) | VAF 132/309 reads (43%) | catalogued as rs1274329845; called by muse, mutect2
- KCNB1 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 252/518 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs750157634, COSV65566603; ClinVar: uncertain significance; called by muse, varscan2
- KCNC2 | c.1664del p.P555Qfs*24 | Frame Shift Del (DEL) | VAF 120/310 reads (39%) | catalogued as rs772232838, COSV54377857; called by mutect2, pindel, varscan2
- KCNG2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 150/342 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs867780231, COSV60269888; called by muse, mutect2, varscan2
- KCNJ15 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 189/396 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs749926649, COSV60810479; called by muse, mutect2, varscan2
- KCNJ2 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 160/314 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54660555; called by muse, varscan2
- KCNJ8 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 183/370 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs762588905, COSV53716118, COSV99557432; called by muse, mutect2, varscan2
- KCNK5 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 153/320 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.416); catalogued as rs149850007; called by muse, mutect2, varscan2
- KCNN3 | c.1432G>A p.V478I | Missense Mutation (SNP) | VAF 124/263 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs148925371, COSV99678926; called by muse, mutect2, varscan2
- KCNQ2 | c.2602G>A p.A868T (on ENST00000359125 / NM_172107.4; = p.A840T on NM_004518.6) | Missense Mutation (SNP) | VAF 180/384 reads (47%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.015); catalogued as rs774595024; called by muse, mutect2, varscan2
- KCNQ5 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 142/314 reads (45%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs750000204, COSV59658622; called by muse, mutect2, varscan2
- KCNT2 | c.2602C>T p.R868W | Missense Mutation (SNP) | VAF 103/203 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1246360892, COSV54104458; called by muse, mutect2, varscan2
- KCNU1 | c.1747A>G p.N583D | Missense Mutation (SNP) | VAF 119/302 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs761489310; called by muse, mutect2, varscan2
- KCNV2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 310/610 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.131); catalogued as rs746873819; called by muse, mutect2, varscan2
- KDM1A | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1326673098; called by muse, mutect2, varscan2
- KDM2A | c.2599G>T p.D867Y | Missense Mutation (SNP) | VAF 276/592 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs1235781109; called by muse, varscan2
- KDM2B | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 213/441 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1437556978; called by muse, mutect2, varscan2
- KDM6B | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 297/570 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs866351379; called by muse, mutect2, varscan2
- KIAA0100 | c.3118C>T p.R1040W | Missense Mutation (SNP) | VAF 206/388 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as rs766293490; called by muse, mutect2, varscan2
- KIAA0408 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 153/334 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752186715; called by muse, mutect2, varscan2
- KIAA1586 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs747974820, COSV66056587; called by muse, mutect2, varscan2
- KIAA1755 | c.2986C>T p.R996C | Missense Mutation (SNP) | VAF 248/540 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs556803461; called by muse, mutect2
- KIAA1841 | c.1751del p.K584Rfs*40 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | catalogued as rs1247673930, COSV54372430; called by mutect2, varscan2
- KIF13B | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 132/254 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200834673; called by muse, mutect2, varscan2
- KIF16B | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 143/290 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478305353, COSV61705892; called by muse, mutect2, varscan2
- KIF18B | c.1015T>C p.Y339H | Missense Mutation (SNP) | VAF 252/462 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.645); catalogued as COSV100191882; called by muse, mutect2, varscan2
- KIF19 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 208/394 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as rs748179750; called by muse, mutect2, varscan2
- KIF1A | c.3556G>T p.G1186C | Missense Mutation (SNP) | VAF 294/559 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57493419; called by muse, mutect2, varscan2
- KIF1B | c.1697G>A p.R566H (on ENST00000377086 / NM_001365952.1; = p.R520H on NM_015074.3) | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as rs751881065; called by muse, mutect2, varscan2
- KIF21A | c.3703del p.I1235Ffs*7 (on ENST00000361418 / NM_001378440.1; = p.I1222Ffs*7 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 58/146 reads (40%) | catalogued as rs761074592; called by mutect2, varscan2
- KIF6 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 142/329 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs780453398, COSV54678498, COSV54690752; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 89/585 reads (15%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLF18 | c.2598dup p.Q867Afs*7 | Frame Shift Ins (INS) | VAF 89/218 reads (41%) | catalogued as rs1459439813; called by mutect2, pindel, varscan2
- KLHL17 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 354/753 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1242895384; called by muse, mutect2
- KLK4 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 151/298 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756500260; called by muse, mutect2, varscan2
- KMT2B | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 252/507 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.543); catalogued as rs752655321, COSV52890053; called by muse, mutect2, varscan2
- KRT34 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 228/518 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs375548630; called by muse, mutect2, varscan2
- KRTAP4-11 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 422/1075 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs759641505, COSV66948487; called by muse, mutect2, varscan2
- KRTAP9-2 | c.257G>A p.C86Y | Missense Mutation (SNP) | VAF 403/878 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs200569975; called by muse, mutect2, varscan2
- KSR1 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 165/335 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as rs1210154778; called by muse, mutect2, varscan2
- KYNU | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 145/276 reads (53%) | catalogued as rs779681494, COSV51592078; called by muse, mutect2, varscan2
- L1TD1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs764969897, COSV63134058; called by muse, mutect2, varscan2
- LAMA1 | c.6463C>A p.L2155I | Missense Mutation (SNP) | VAF 105/247 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67536045; called by muse, mutect2, varscan2
- LAMA3 | c.4193G>A p.R1398H | Missense Mutation (SNP) | VAF 182/367 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs558309965; called by muse, mutect2, varscan2
- LAMA5 | c.9401G>A p.R3134H | Missense Mutation (SNP) | VAF 295/583 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs535545260, COSV53361977; called by muse, mutect2, varscan2
- LAMB1 | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 174/353 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.612); catalogued as rs766693167, COSV55965296, COSV55968086, COSV99739799; called by muse, mutect2, varscan2
- LCAT | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 158/346 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as rs771517943; called by muse, mutect2, varscan2
- LIG3 | c.395del p.G132Vfs*3 | Frame Shift Del (DEL) | VAF 94/292 reads (32%) | catalogued as COSV52005906; called by pindel, varscan2
- LILRA1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 236/1008 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as rs757252403, COSV52180809, COSV52181349; called by muse, mutect2, varscan2
- LMNA | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 213/451 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs879253898, COSV61543943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPAR5 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 119/643 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1159267322; called by muse, mutect2, varscan2
- LPAR6 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 149/305 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748857151; called by muse, mutect2, varscan2
- LPCAT1 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 254/531 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1242623674; called by muse, varscan2
- LRP12 | c.1351dup p.C451Lfs*9 | Frame Shift Ins (INS) | VAF 174/358 reads (49%) | catalogued as rs35928649; called by mutect2, varscan2
- LRP1B | c.6458G>A p.G2153D | Missense Mutation (SNP) | VAF 103/221 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as rs202108597; called by muse, mutect2, varscan2
- LRPPRC | c.988T>C p.C330R | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs760507752; called by muse, mutect2, varscan2
- LRRC31 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs753331732; called by muse, mutect2, varscan2
- LRRC32 | c.1423T>C p.S475P | Missense Mutation (SNP) | VAF 269/512 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV52632641; called by muse, mutect2, varscan2
- LRRC37A2 | c.5072C>T p.T1691M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs746004658; called by mutect2, varscan2
- LRRC56 | c.816del p.I273Sfs*137 | Frame Shift Del (DEL) | VAF 250/624 reads (40%) | catalogued as COSV99530308; called by mutect2, pindel, varscan2
- LRRD1 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 84/204 reads (41%) | catalogued as rs781110436; called by muse, mutect2, varscan2
- LSG1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 157/300 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542613557, COSV54569576; called by muse, mutect2, varscan2
- LYN | c.327del p.E110Kfs*15 | Frame Shift Del (DEL) | VAF 95/231 reads (41%) | catalogued as rs1266824391, COSV99066642; called by mutect2, pindel, varscan2
- LYST | c.9943C>T p.R3315C | Missense Mutation (SNP) | VAF 109/218 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1299376147, COSV101088023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MADD | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 231/553 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); catalogued as rs374366101; called by muse, mutect2, varscan2
- MAGEC1 | c.1617G>A p.W539* | Nonsense Mutation (SNP) | VAF 242/243 reads (100%) | catalogued as COSV99595104; called by muse, mutect2, varscan2
- MAGEC1 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs147835720, COSV53573381; called by muse, mutect2, varscan2
- MAGED1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 94/252 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as COSV100431633; called by muse, varscan2
- MAN2A1 | c.3282G>T p.K1094N | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99811882; called by muse, mutect2, varscan2
- MAN2A2 | c.2493dup p.V832Rfs*6 | Frame Shift Ins (INS) | VAF 132/268 reads (49%) | catalogued as rs755100936; called by mutect2, varscan2
- MAOB | c.35dup p.G13Rfs*13 | Frame Shift Ins (INS) | VAF 299/509 reads (59%) | catalogued as rs1287902498; called by pindel, varscan2
- MAP2K3 | c.124dup p.R42Pfs*17 (on ENST00000342679 / NM_145109.3; = p.R13Pfs*17 on NM_002756.4) | Frame Shift Ins (INS) | VAF 146/431 reads (34%) | catalogued as COSV100384541; called by mutect2, varscan2
- MAP3K1 | c.14C>G p.A5G | Missense Mutation (SNP) | VAF 18/654 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as rs1561156036; called by muse, mutect2
- MAP3K10 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 194/400 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs749475788; called by muse, mutect2, varscan2
- MAP3K7 | c.504dup p.T169Dfs*7 | Frame Shift Ins (INS) | VAF 105/256 reads (41%) | catalogued as rs1279022470; called by mutect2, pindel, varscan2
- MAP4K2 | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 152/298 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs151089831; called by muse, varscan2
- MAPK3 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 111/261 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as rs1287735708; called by muse, mutect2, varscan2
- MAPK8IP1 | c.658del p.Q220Rfs*56 | Frame Shift Del (DEL) | VAF 366/857 reads (43%) | catalogued as rs781009214; called by mutect2, pindel, varscan2
- MAPKBP1 | c.4279C>T p.R1427C (on ENST00000456763 / NM_001128608.2; = p.R1421C on NM_014994.3) | Missense Mutation (SNP) | VAF 287/573 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); catalogued as rs369279683; called by muse, mutect2, varscan2
- MARVELD2 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 196/448 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); catalogued as rs199777123; called by muse, mutect2, varscan2
- MATN2 | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 204/403 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211048863, COSV54717814; called by muse, mutect2, varscan2
- MBTPS1 | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 109/211 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs780652782; called by muse, mutect2, varscan2
- MC5R | c.223G>C p.V75L | Missense Mutation (SNP) | VAF 32/485 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV61254486; called by muse, mutect2
- MCF2L | c.1546G>A p.A516T (on ENST00000375608; = p.A484T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 213/428 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs765411448; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 66/148 reads (45%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 32/200 reads (16%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDN1 | c.6500C>T p.T2167M | Missense Mutation (SNP) | VAF 170/377 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1307137280, COSV104428637; called by muse, mutect2, varscan2
- MED12L | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777002012, COSV56372488; called by muse, mutect2, varscan2
- MED15 | c.1349C>A p.P450H (on ENST00000263205 / NM_001003891.3; = p.P410H on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/591 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53029996; called by mutect2, varscan2
- MEI1 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 85/455 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs767987047, COSV55903081; called by muse, mutect2, varscan2
- MFNG | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 303/642 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV52659354; called by muse, mutect2, varscan2
- MFSD9 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 91/462 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.052); catalogued as COSV51496278; called by muse, mutect2, varscan2
- MGA | c.4576C>T p.R1526W | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754941833; called by muse, mutect2, varscan2
- MIDEAS | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 302/664 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1422514772; called by muse, mutect2, varscan2
- MINAR1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 240/485 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs374800681; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 154/336 reads (46%) | catalogued as rs751465048; called by mutect2, varscan2
- MMP20 | c.359del p.N120Ifs*3 | Frame Shift Del (DEL) | VAF 86/194 reads (44%) | catalogued as rs759614533, CD134338; called by mutect2, varscan2
- MORN3 | c.378G>A p.W126* | Nonsense Mutation (SNP) | VAF 135/665 reads (20%) | catalogued as rs563056533; called by muse, mutect2, varscan2
- MROH2B | c.2632T>C p.W878R | Missense Mutation (SNP) | VAF 142/330 reads (43%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.939); catalogued as COSV68189951; called by muse, mutect2, varscan2
- MSANTD1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 306/630 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779952291; called by muse, mutect2, varscan2
- MTHFD1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 150/321 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs1437397220, COSV53701640; called by muse, mutect2, varscan2
- MTMR10 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 220/409 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs200305641; called by muse, mutect2, varscan2
- MTRR | c.655G>A p.E219K (on ENST00000264668; = p.E192K on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 189/393 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs143058455; called by muse, mutect2, varscan2
- MTURN | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 149/356 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs781564824, COSV61023382; called by muse, mutect2, varscan2
- MUC16 | c.37855C>T p.R12619C | Missense Mutation (SNP) | VAF 144/505 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs765697877, COSV67444013; called by muse, mutect2, varscan2
- MUC16 | c.4957G>A p.G1653R | Missense Mutation (SNP) | VAF 207/440 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); catalogued as rs1483575555, COSV101199457; called by muse, mutect2, varscan2
- MUC2 | c.2494G>A p.V832M | Missense Mutation (SNP) | VAF 238/522 reads (46%) | SIFT tolerated (0.23); catalogued as rs533770619; called by muse, mutect2, varscan2
- MUC4 | c.5944G>A p.A1982T | Missense Mutation (SNP) | VAF 256/1032 reads (25%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.125); catalogued as rs763666093, COSV62137577; called by mutect2, varscan2
- MUC5B | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 333/701 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as rs370603601; called by muse, mutect2, varscan2
- MVK | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 123/285 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as rs1241492890, CM129897; called by muse, mutect2, varscan2
- MVP | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 274/519 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs200801648; called by muse, varscan2
- MYH14 | c.3614G>A p.R1205H | Missense Mutation (SNP) | VAF 276/538 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs368918699, COSV51821340; called by muse, mutect2, varscan2
- MYH14 | c.5765G>A p.R1922H | Missense Mutation (SNP) | VAF 326/664 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs781030522, COSV51812325; called by muse, mutect2, varscan2
- MYH6 | c.5593C>T p.R1865W | Missense Mutation (SNP) | VAF 101/218 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs759499155, COSV59304722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK3 | c.619dup p.I207Nfs*9 | Frame Shift Ins (INS) | VAF 245/607 reads (40%) | catalogued as rs772243370; called by mutect2, pindel, varscan2
- MYO10 | c.5645C>T p.T1882M | Missense Mutation (SNP) | VAF 194/411 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs532130077; called by muse, mutect2, varscan2
- MYO15A | c.7786A>G p.R2596G | Missense Mutation (SNP) | VAF 138/321 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs886052677, COSV52751766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.8488C>G p.P2830A | Missense Mutation (SNP) | VAF 162/325 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV52764202; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 68/158 reads (43%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1G | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 173/360 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as rs146602744; called by muse, mutect2, varscan2
- MYO7A | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs782468194, COSV68683537; called by muse, mutect2, varscan2
- MYO9B | c.6048_6049dup p.A2017Gfs*37 | Frame Shift Ins (INS) | VAF 193/568 reads (34%) | catalogued as COSV55728921; called by pindel, varscan2
- MZF1 | c.2162G>A p.S721N | Missense Mutation (SNP) | VAF 168/367 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.861); catalogued as rs891264501; called by muse, mutect2, varscan2
- NAT10 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 126/266 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57662922; called by muse, mutect2, varscan2
- NBEAL1 | c.6331C>T p.R2111C | Missense Mutation (SNP) | VAF 149/321 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757998545, COSV68915896, COSV68917402; called by muse, mutect2, varscan2
- NCKAP5 | c.1559A>G p.H520R | Missense Mutation (SNP) | VAF 189/389 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as rs775209047, COSV58443359; called by muse, mutect2, varscan2
- NCOR1 | c.6467C>T p.P2156L | Missense Mutation (SNP) | VAF 174/347 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.04); catalogued as rs773322630, COSV51973195; called by muse, mutect2, varscan2
- NCOR2 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 168/377 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs371730972; called by muse, mutect2, varscan2
- NEB | c.5183C>T p.A1728V | Missense Mutation (SNP) | VAF 159/367 reads (43%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.547); catalogued as COSV51118205; called by muse, mutect2, varscan2
- NEIL1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 189/373 reads (51%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs749895649, COSV51226476; called by muse, mutect2, varscan2
- NEU1 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 304/679 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs564560226, COSV57669142; called by muse, mutect2, varscan2
- NEU2 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 279/540 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201616110; called by muse, mutect2, varscan2
- NFKBIL1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 316/646 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs201714450, COSV65990282; called by muse, mutect2, varscan2
- NID2 | c.2950G>A p.V984M | Missense Mutation (SNP) | VAF 103/407 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs772923728, COSV53493033; called by muse, mutect2, varscan2
- NLRP2 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 19/511 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747930528; called by muse, mutect2
- NMUR1 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 208/447 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376710654; called by muse, mutect2, varscan2
- NOL4L | c.396dup p.Y133Lfs*18 | Frame Shift Ins (INS) | VAF 128/256 reads (50%) | catalogued as rs751187638; called by mutect2, varscan2
- NOL8 | c.1169del p.N390Mfs*45 | Frame Shift Del (DEL) | VAF 43/183 reads (23%) | catalogued as rs757782481; called by mutect2, varscan2
- NPHP4 | c.2807C>T p.T936M | Missense Mutation (SNP) | VAF 165/400 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs201074950; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NRM | c.187del p.L63Wfs*23 | Frame Shift Del (DEL) | VAF 129/678 reads (19%) | catalogued as rs757081047; called by mutect2, pindel, varscan2
- NSUN3 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 120/283 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.753); catalogued as COSV58933952; called by muse, mutect2, varscan2
- NUDT2 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 127/254 reads (50%) | catalogued as rs148119952; called by muse, mutect2, varscan2
- NUDT6 | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 148/343 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs1469563599, COSV58647563; called by muse, mutect2, varscan2
- NUP210L | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 105/215 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs975021704; called by muse, mutect2, varscan2
- OAF | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 159/364 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749392944, COSV61109591; called by muse, mutect2, varscan2
- OAS3 | c.1658-1G>A p.X553_splice | Splice Site (SNP) | VAF 97/203 reads (48%) | catalogued as rs1466072087; called by muse, mutect2, varscan2
- OAT | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 107/210 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs776703980; called by muse, mutect2, varscan2
- OGDHL | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 180/368 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs748297322; called by muse, mutect2, varscan2
- OGN | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147797196; called by muse, mutect2, varscan2
- OLFML2A | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 232/497 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921849502; called by muse, mutect2, varscan2
- OPRL1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 415/804 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs772654648; called by muse, mutect2, varscan2
- OR10V1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs1410039901; called by muse, mutect2, varscan2
- OR2G3 | c.186dup p.L63Sfs*14 | Frame Shift Ins (INS) | VAF 181/452 reads (40%) | catalogued as COSV60682833; called by mutect2, pindel, varscan2
- OR2M2 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 169/344 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV62897890; called by muse, mutect2, varscan2
- OR2T34 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 233/802 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1161878210; called by muse, mutect2, varscan2
- OR2W3 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 208/425 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs147318633; called by muse, mutect2, varscan2
- OR4C16 | c.89dup p.L30Ffs*11 | Frame Shift Ins (INS) | VAF 120/236 reads (51%) | catalogued as rs752324980; called by mutect2, varscan2
- OR51E1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 189/391 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759603811, COSV67809620; called by muse, mutect2, varscan2
- OR51S1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 118/447 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV59058489; called by muse, mutect2, varscan2
- OR5K4 | c.864T>A p.S288R | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100721329; called by muse, mutect2, varscan2
- OR8H1 | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 178/373 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV57293733; called by muse, mutect2, varscan2
- OSBPL10 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 206/392 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as rs751308846, COSV101158686; called by muse, mutect2, varscan2
- OTOF | c.1937G>A p.G646D | Missense Mutation (SNP) | VAF 159/378 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV55495582; called by muse, mutect2, varscan2
- OTOG | c.7435C>T p.R2479C | Missense Mutation (SNP) | VAF 335/643 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs1238306172; called by muse, mutect2, varscan2
- PACC1 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 141/305 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs373475631; called by muse, mutect2, varscan2
- PALM | c.775dup p.A259Gfs*53 | Frame Shift Ins (INS) | VAF 360/944 reads (38%) | catalogued as rs755308979; called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.366G>T p.K122N (on ENST00000374531 / NM_001037293.2; = p.K120N on NM_007203.5) | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.067); catalogued as COSV100092338; called by muse, mutect2, varscan2
- PAN2 | c.3265C>T p.R1089W (on ENST00000425394 / NM_001127460.3; = p.R1085W on NM_014871.5) | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56265022; called by muse, mutect2, varscan2
- PARP2 | c.1705A>G p.M569V | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as rs749078070; called by muse, mutect2, varscan2
- PCDH10 | c.2180T>C p.F727S | Missense Mutation (SNP) | VAF 272/553 reads (49%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.986); catalogued as rs762190073; called by muse, varscan2
- PCDH12 | c.3517A>G p.K1173E | Missense Mutation (SNP) | VAF 179/414 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1309320741; called by muse, mutect2, varscan2
- PCDHA9 | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 483/941 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as rs782709396, COSV65326472; called by muse, mutect2, varscan2
- PCDHB9 | c.2187G>T p.E729D | Missense Mutation (SNP) | VAF 306/704 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs542462731; called by muse, mutect2, varscan2
- PCDHGA5 | c.2421G>T p.Q807H | Missense Mutation (SNP) | VAF 90/182 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV53977202; called by muse, mutect2, varscan2
- PCDHGC3 | c.2071A>G p.T691A | Missense Mutation (SNP) | VAF 222/485 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs558944208; called by muse, mutect2
- PCDHGC4 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 195/404 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52749630; called by muse, varscan2
- PCED1A | c.950_952del p.S317del | In Frame Del (DEL) | VAF 153/371 reads (41%) | catalogued as rs769680922; called by pindel, varscan2
- PCLO | c.14499T>A p.D4833E | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs1476614728; called by muse, mutect2, varscan2
- PCNX2 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 190/389 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs745867353, COSV50786268, COSV50816911; called by muse, mutect2, varscan2
- PCNX3 | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 185/445 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs779060583; called by muse, mutect2, varscan2
- PDE2A | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 169/385 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1198044269; called by muse, mutect2, varscan2
- PDGFD | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.086); catalogued as rs773977234; called by muse, mutect2, varscan2
- PDZRN3 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 232/492 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376105538; called by muse, varscan2
- PDZRN4 | c.2261G>A p.R754H (on ENST00000402685 / NM_001164595.2; = p.R496H on NM_013377.4) | Missense Mutation (SNP) | VAF 136/271 reads (50%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.97); catalogued as rs367580859, COSV54211224; called by muse, mutect2, varscan2
- PEDS1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 157/329 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.416); catalogued as rs143177329; called by muse, mutect2, varscan2
- PEG3 | c.3676C>T p.R1226* | Nonsense Mutation (SNP) | VAF 15/467 reads (3%) | catalogued as rs867143279, COSV55638988; called by muse, mutect2
- PFKP | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 272/515 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as rs749743485; called by muse, mutect2, varscan2
- PGAM2 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 60/804 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs770622502, COSV51979341; called by muse, mutect2
- PGAP3 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as rs367729979; called by muse, mutect2, varscan2
- PHC1 | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 138/307 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as rs1317553289, COSV50003508; called by muse, mutect2, varscan2
- PHIP | c.2965A>C p.K989Q | Missense Mutation (SNP) | VAF 116/230 reads (50%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.915); catalogued as rs760137132; called by muse, mutect2, varscan2
- PHKG2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 258/518 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as rs138299462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PID1 | c.619G>A p.E207K (on ENST00000354069 / NM_001330156.1; = p.E205K on NM_017933.5) | Missense Mutation (SNP) | VAF 199/400 reads (50%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.951); catalogued as rs1485377604, COSV100819515; called by muse, mutect2, varscan2
- PIEZO2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 190/415 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs760374118; called by muse, mutect2, varscan2
- PIGQ | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 166/399 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs777091419; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 173/434 reads (40%) | catalogued as rs749506841; called by mutect2, varscan2
- PIK3CD | c.2906G>A p.R969H | Missense Mutation (SNP) | VAF 248/528 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs761274254, COSV63127935; called by muse, mutect2, varscan2
- PIK3R2 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 239/508 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.286); catalogued as rs765749303; called by muse, mutect2, varscan2
- PIP4P2 | c.538del p.I180Sfs*21 | Frame Shift Del (DEL) | VAF 111/265 reads (42%) | catalogued as rs1158949501; called by mutect2, pindel, varscan2
- PITPNM1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 347/766 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1000389359; called by muse, mutect2, varscan2
- PITPNM2 | c.1684G>A p.V562I | Missense Mutation (SNP) | VAF 187/375 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs756970216; called by muse, mutect2, varscan2
- PKD1 | c.10934G>A p.R3645H (on ENST00000262304 / NM_001009944.3; = p.R3644H on NM_000296.4) | Missense Mutation (SNP) | VAF 261/551 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753960606; called by muse, mutect2, varscan2
- PKD1 | c.10747G>T p.G3583C (on ENST00000262304 / NM_001009944.3; = p.G3582C on NM_000296.4) | Missense Mutation (SNP) | VAF 354/767 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV51922646; called by muse, mutect2, varscan2
- PKP2 | c.1841T>G p.L614R | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM1310718; called by muse, mutect2, varscan2
- PLCE1 | c.3836C>T p.S1279L | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs575762810, COSV53365820; called by muse, mutect2, varscan2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 93/212 reads (44%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHG4B | c.3541G>A p.A1181T (on ENST00000283426; = p.A1537T on NM_052909.5) | Missense Mutation (SNP) | VAF 302/599 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as rs756428760; called by muse, mutect2, varscan2
- PLEKHM2 | c.1346C>A p.P449Q | Missense Mutation (SNP) | VAF 255/548 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV65398037; called by muse, mutect2, varscan2
- PLEKHO1 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 272/526 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs374753885; called by muse, mutect2, varscan2
- PLS1 | c.1133T>C p.L378P | Missense Mutation (SNP) | VAF 123/235 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374808612; called by muse, mutect2, varscan2
- PLVAP | c.47dup p.S17Qfs*106 | Frame Shift Ins (INS) | VAF 192/518 reads (37%) | catalogued as rs768884250; called by mutect2, pindel, varscan2
- PLXNA2 | c.1393dup p.H465Pfs*27 | Frame Shift Ins (INS) | VAF 157/323 reads (49%) | catalogued as rs752105673; called by mutect2, varscan2
- PLXNB2 | c.4307C>T p.P1436L | Missense Mutation (SNP) | VAF 254/510 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332845035; called by muse, mutect2, varscan2
- PNLIPRP2 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 86/462 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs372996914; called by muse, mutect2, varscan2
- POGK | c.169dup p.S57Ffs*3 | Frame Shift Ins (INS) | VAF 167/381 reads (44%) | catalogued as COSV100902417; called by mutect2, pindel, varscan2
- POLD1 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 252/515 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs1354117345, COSV70954141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLD1 | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 204/398 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309243644, COSV70954174; ClinVar: uncertain significance; called by muse, varscan2
- POLE | c.5074C>T p.P1692S | Missense Mutation (SNP) | VAF 169/363 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57683604; called by muse, mutect2, varscan2
- POLR2F | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 425/856 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs1163952812; called by muse, mutect2, varscan2
- POLRMT | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 401/882 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751158506; called by muse, mutect2, varscan2
- POR | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 314/652 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554558909; called by muse, mutect2, varscan2
- POTEM | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as rs774821444, COSV101304560; called by mutect2, varscan2
- PPIG | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53646961; called by muse, mutect2, varscan2
- PPP1R13L | c.1683dup p.P562Afs*10 | Frame Shift Ins (INS) | VAF 292/870 reads (34%) | catalogued as rs780494005; called by pindel, varscan2
- PPP1R37 | c.102dup p.A35Rfs*83 | Frame Shift Ins (INS) | VAF 364/889 reads (41%) | catalogued as rs1287576490; called by mutect2, pindel, varscan2
- PRAG1 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 314/533 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV58163004; called by muse, mutect2, varscan2
- PRAM1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 299/578 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs369144041, COSV99725231; called by muse, mutect2, varscan2
- PRC1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776619186, COSV62694369; called by muse, mutect2, varscan2
- PRDM1 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 215/483 reads (45%) | catalogued as COSV64846690, COSV64847475; called by muse, mutect2, varscan2
- PRDM10 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 230/458 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754656173; called by muse, varscan2
- PRDM10 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 213/429 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755600909, COSV58805456; called by muse, varscan2
- PRKAA2 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 171/319 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100982757; called by muse, mutect2, varscan2
- PRKACG | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 110/562 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as COSV55245344; called by muse, mutect2, varscan2
- PRKAG2 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 131/264 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.096); catalogued as rs540525001, COSV55237918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKDC | c.3806C>T p.T1269M | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs772192357; called by muse, mutect2, varscan2
- PRPF40B | c.1747G>A p.A583T (on ENST00000380281; = p.A570T on NM_012272.3) | Missense Mutation (SNP) | VAF 196/413 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs957897204; called by muse, mutect2, varscan2
- PRR12 | c.2653C>A p.P885T (on ENST00000615927; = p.P1706T on NM_020719.3) | Missense Mutation (SNP) | VAF 275/576 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV69817778; called by muse, mutect2, varscan2
- PRR22 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 227/471 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs1012220296; called by muse, mutect2, varscan2
- PRR23D1 | c.150dup p.P51Tfs*27 | Frame Shift Ins (INS) | VAF 79/418 reads (19%) | catalogued as rs769392464; called by mutect2, varscan2
- PRR30 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 245/519 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs1022564387; called by muse, mutect2, varscan2
- PRR5 | c.577G>A p.V193M (on ENST00000336985 / NM_181333.4; = p.V184M on NM_015366.4) | Missense Mutation (SNP) | VAF 217/462 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as rs377481820; called by muse, mutect2, varscan2
- PRSS35 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 161/344 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758944799; called by muse, mutect2, varscan2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 210/585 reads (36%) | catalogued as COSV99194092; called by pindel, varscan2
- PSKH1 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs777852511; called by muse, mutect2, varscan2
- PSMA1 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 149/303 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67165918; called by muse, varscan2
- PTCH1 | c.3470C>T p.A1157V | Missense Mutation (SNP) | VAF 177/325 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0.183); catalogued as COSV59479162; called by muse, mutect2, varscan2
- PTDSS1 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 172/320 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.572); catalogued as rs746427419, COSV100428539, COSV100429013; called by muse, varscan2
- PTGR2 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 77/132 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755954716, COSV50865414; called by muse, mutect2, varscan2
- PTK7 | c.2094del p.Y699Tfs*3 | Frame Shift Del (DEL) | VAF 185/471 reads (39%) | catalogued as rs1291356333, COSV57846491; called by mutect2, pindel, varscan2
- PTPRG | c.3151C>T p.P1051S | Missense Mutation (SNP) | VAF 171/335 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as rs987673426; called by muse, mutect2, varscan2
- PTX4 | c.883C>T p.R295* (on ENST00000447419 / NM_001328608.2; = p.R290* on NM_001013658.1) | Nonsense Mutation (SNP) | VAF 264/606 reads (44%) | catalogued as rs757126891, COSV53518953; called by muse, mutect2, varscan2
- PVALB | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 164/388 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs567942924, COSV53412726; called by muse, mutect2, varscan2
- PYGL | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 178/335 reads (53%) | catalogued as rs998126774, COSV53583974; called by muse, mutect2, varscan2
- QRICH2 | c.2047C>T p.H683Y | Missense Mutation (SNP) | VAF 406/811 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs573451023; called by muse, mutect2, varscan2
- R3HCC1 | c.242T>C p.F81S (on ENST00000411463; = p.F41S on NM_001136108.3) | Missense Mutation (SNP) | VAF 127/271 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs982227825; called by muse, mutect2, varscan2
- RAB11B | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 304/600 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100033115, COSV60086158; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 370/751 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as rs371078762; called by muse, mutect2, varscan2
- RAB26 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 201/429 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373434519; called by muse, mutect2, varscan2
- RAB35 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 204/474 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); catalogued as rs768711168; called by muse, mutect2, varscan2
- RAB3GAP1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 137/281 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.603); catalogued as COSV51479931; called by muse, mutect2, varscan2
- RADX | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1303063712; called by muse, mutect2, varscan2
- RAF1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 171/325 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52579905, COSV52583001; called by muse, mutect2, varscan2
- RAI1 | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 293/615 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV99884509; called by muse, mutect2, varscan2
- RALBP1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 124/243 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as rs768270450; called by muse, mutect2, varscan2
- RALY | c.820C>T p.R274W (on ENST00000246194 / NM_016732.3; = p.R258W on NM_007367.4) | Missense Mutation (SNP) | VAF 242/506 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs141651101; called by muse, varscan2
- RAMP3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 199/441 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs762889499, COSV54245059; called by muse, mutect2, varscan2
- RAPGEF3 | c.1543C>T p.R515W (on ENST00000389212; = p.R473W on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/291 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377464139; called by muse, mutect2, varscan2
- RAPGEF5 | c.753G>T p.E251D (on ENST00000401957 / NM_001367602.2; = p.E554D on NM_012294.5) | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59782026; called by muse, mutect2, varscan2
- RAPGEFL1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 358/808 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs749265100; called by muse, mutect2, varscan2
- RASGEF1A | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 141/339 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs747346627, COSV65667499; called by muse, mutect2, varscan2
- RB1CC1 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 182/367 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151174558; called by muse, mutect2, varscan2
- RBBP6 | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 159/342 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1174821855, COSV60508519; called by muse, mutect2, varscan2
- RBM10 | c.2261C>T p.T754I | Missense Mutation (SNP) | VAF 94/368 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV61311001; called by muse, varscan2
- RBM7 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 135/244 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as rs779238918; called by muse, mutect2, varscan2
- RBMXL2 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 352/620 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as rs1390556119; called by muse, varscan2
- RCAN3 | c.638dup p.N213Kfs*21 | Frame Shift Ins (INS) | VAF 223/570 reads (39%) | catalogued as rs773811205; called by mutect2, pindel, varscan2
- RCN1 | c.690G>A p.A230= | Splice Region (SNP) | VAF 82/184 reads (45%) | catalogued as rs781222739; called by muse, mutect2, varscan2
- RELB | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 371/828 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1369496355, COSV55510814; called by muse, mutect2, varscan2
- RERE | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 188/439 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as rs1372438049, COSV61942792; called by muse, varscan2
- RET | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 226/457 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as rs377767410, CM035806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REV3L | c.5774G>A p.R1925Q | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs776974963; called by muse, mutect2, varscan2
- RGPD4 | c.5233G>A p.E1745K | Missense Mutation (SNP) | VAF 111/309 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV61748264; called by muse, mutect2, varscan2
- RHBG | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 173/331 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs778886045; called by muse, mutect2, varscan2
- RIF1 | c.3227G>A p.R1076Q | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54622313; called by muse, mutect2, varscan2
- RIMKLA | c.946G>T p.G316* | Nonsense Mutation (SNP) | VAF 16/447 reads (4%) | catalogued as COSV68909644, COSV68909788; called by muse, mutect2
- RIMS1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 134/308 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs1411730533, COSV53449107, COSV99330722; called by muse, mutect2, varscan2
- RINL | c.919C>T p.R307W (on ENST00000591812 / NM_001195833.2; = p.R193W on NM_198445.4) | Missense Mutation (SNP) | VAF 191/414 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749779818; called by muse, mutect2, varscan2
- RIPOR3 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 206/434 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as rs770915755, COSV99246561; called by muse, mutect2, varscan2
- RNASEH2B | c.509del p.K170Rfs*9 | Frame Shift Del (DEL) | VAF 84/189 reads (44%) | catalogued as rs1085307091, COSV60747894; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RND2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 186/368 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1182099592, COSV56816512; called by muse, varscan2
- RNF111 | c.2884C>T p.H962Y (on ENST00000557998 / NM_001270530.1; = p.H954Y on NM_017610.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/192 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV62086592; called by muse, mutect2, varscan2
- RNF144A | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 143/293 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs771191884, COSV57986111; called by muse, mutect2, varscan2
- RNF157 | c.1779A>G p.I593M | Missense Mutation (SNP) | VAF 121/229 reads (53%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs761741928; called by muse, mutect2, varscan2
- RNF157 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 114/260 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs1194903176; called by muse, varscan2
- RNF213 | c.7966G>A p.A2656T | Missense Mutation (SNP) | VAF 204/444 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs747894921; called by muse, mutect2, varscan2
2,099 further variants in this file (1,343 protein-altering or splice-affecting, 647 silent, 109 other) are not listed here.
